Somatic mutation profile of tumor specimen TCGA-C5-A8XI-01A (aliquot TCGA-C5-A8XI-01A-11D-A37N-09) from TCGA case TCGA-C5-A8XI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 69.0 years (25,220 days).
Specimen TCGA-C5-A8XI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c771379f-7632-4d90-9b74-6c981ddeabd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8XI-10A (Blood Derived Normal), aliquot TCGA-C5-A8XI-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd0f6319-f765-49d9-953f-693c32107723

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 38, Silent 10, Splice Region 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100202243; called by muse, mutect2, varscan2
- ARFGEF3 | c.3472G>A p.D1158N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99294741; called by muse, mutect2, varscan2
- BRPF3 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326193; called by muse, mutect2, varscan2
- C9 | c.1294G>A p.G432R | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99662569; called by muse, mutect2, varscan2
- CCAR1 | c.554G>A p.R185K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99771430; called by muse, varscan2
- CCDC148 | c.1156A>G p.M386V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV99321450; called by muse, mutect2, varscan2
- CDCP1 | c.1975C>A p.L659I | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as COSV56108035; called by muse, mutect2
- COL22A1 | c.2517G>T p.K839N | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1325231035, COSV57321611; called by muse, mutect2, varscan2
- CSMD3 | c.7865C>T p.A2622V (on ENST00000297405 / NM_001363185.1; = p.A2518V on NM_052900.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs752866181, COSV52185717, COSV52240395; called by muse, mutect2, varscan2
- DCAF15 | c.199A>T p.N67Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV99586952; called by muse, mutect2, varscan2
- DPF3 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757444001, COSV63503378; called by muse, mutect2, varscan2
- DPP6 | c.2341G>A p.E781K (on ENST00000377770 / NM_001364500.2; = p.E719K on NM_001936.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100128177; called by muse, mutect2, varscan2
- FAM9B | c.261G>C p.L87F | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.961); catalogued as COSV100511123, COSV100511158, COSV59120283; called by muse, mutect2, varscan2
- FOLH1 | c.1175C>A p.A392E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99923962; called by muse, mutect2, varscan2
- GALNT17 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.019); catalogued as rs746500500, COSV61157475; called by muse, mutect2, varscan2
- GK | c.772C>G p.P258A (on ENST00000427190 / NM_001205019.2; = p.P252A on NM_000167.6) | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100971003; called by muse, mutect2, varscan2
- GXYLT1 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99789091; called by muse, mutect2
- KLHL21 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV100887300; called by muse, mutect2
- LILRA6 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs531582888; called by muse, mutect2
- LUZP4 | c.154C>G p.Q52E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV100904887; called by muse, mutect2, varscan2
- MAGT1 | c.576G>T p.L192F (on ENST00000618282 / NM_001367916.1; = p.L224F on NM_032121.5) | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV100800459; called by muse, mutect2, varscan2
- MFSD11 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs907380122, COSV60620499; called by muse, mutect2, varscan2
- MGRN1 | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as COSV99274875; called by muse, mutect2
- MYLK | c.3658G>T p.A1220S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV100659651; called by muse, mutect2, varscan2
- MYOF | c.4234G>A p.V1412I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs766655843, COSV100826138; called by muse, mutect2, varscan2
- NCOA1 | c.3164G>A p.R1055Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56048417, COSV56051588; called by muse, mutect2, varscan2
- NLGN4X | c.2044G>A p.G682R | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99324002; called by muse, mutect2, varscan2
- OPCML | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.678); catalogued as rs772092757, COSV100105127; called by muse, mutect2, varscan2
- PPP3CC | c.916A>T p.N306Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99252463; called by muse, mutect2, varscan2
- PROX1 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.15); catalogued as COSV54780495; called by muse, mutect2
- PTGES3L-AARSD1 | c.943A>G p.S315G (on ENST00000421990 / NM_001136042.2; = p.S297G on NM_025267.3) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100799469; called by muse, varscan2
- RBBP8 | c.2561T>C p.V854A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1359966468, COSV100507675; called by muse, mutect2, varscan2
- RBM5 | c.2094G>A p.E698= | Splice Region (SNP) | VAF 5/77 reads (6%) | catalogued as COSV100762502; called by muse, mutect2
- SIM1 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1315267889, COSV53490880; called by muse, mutect2
- SIX3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311723501, CM086937, COSV99578580; called by muse, mutect2, varscan2
- SLC18A2 | c.1340T>A p.I447N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100042083; called by muse, mutect2, varscan2
- SLC4A8 | c.2156G>A p.R719H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs776058582, COSV60657372; called by muse, mutect2, varscan2
- TAPT1 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100461248; called by muse, mutect2
- TRAF5 | c.1579C>T p.H527Y | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1050953881, COSV99807642; called by muse, mutect2, varscan2
- WHAMM | c.2334G>C p.E778D | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54500124, COSV99725243; called by muse, mutect2, varscan2
- PIK3R1 | c.1710_1718del p.I571_L573del (on ENST00000521381 / NM_181523.3; = p.I301_L303del on NM_181504.4) | In Frame Del (DEL) | VAF 15/60 reads (25%) | called by mutect2, pindel, varscan2
- CASS4 | c.2157G>A p.T719= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs374794797, COSV64387452; called by muse, mutect2, varscan2
- CHRM1 | c.252G>A p.T84= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs778921727, COSV61006080; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.60C>T p.H20= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99862701; called by muse, mutect2, varscan2
- GPATCH3 | c.393G>A p.G131= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs1212674647, COSV100658923; called by muse, mutect2, varscan2
- KHDRBS1 | c.1125C>T p.Y375= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs751047839, COSV100306325, COSV56982495; called by muse, mutect2, varscan2
- RGS4 | c.498C>A p.R166= | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as COSV100905613; called by muse, mutect2, varscan2
- TGOLN2 | c.36C>A p.V12= | Silent (SNP) | VAF 8/200 reads (4%) | catalogued as rs1399905400, COSV56405790; called by muse, mutect2
- VWCE | c.2067C>T p.Y689= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs773833904, COSV57112589, COSV57115227; called by muse, mutect2, varscan2
- WWC1 | c.2286C>T p.G762= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs149891366; called by muse, mutect2, varscan2
- ZSCAN30 | c.1476C>T p.T492= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV54352204, COSV99735151; called by muse, mutect2, varscan2
